Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8529, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8529-01A (Primary Tumor).

[page 1 of 5]
Clinical Information

GENERAL INFORMATION

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain ; black & tarry stool ; nausea

Symptoms: Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☒ NO		1 pack	40 (yrs)	2 m ago (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☒ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	an ulceration at the lesser curvature of the stomach	February 25, 2010
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T4 N0 M1	Stage: IV

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Gastrectomy (314)		
Primary Tumor		
Organ	Detailed Location	Size
Stomach tumor	Antrum	5 x 4 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Liver	Right	2 x 2 cm
Surgical Staging		
T4 N0 M1 Stage: IV		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)

Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION

Primary Tumor

Organ	Size	Extension of Tumor	Distance to NAT
Stomach tumor	5 x 4 x 2 cm	Anterior	6 cm

Lymph Nodes

Location	# Examined	# Metastasized

Distant Metastasis

Organ	Detailed Location	Size
Liver	Right	2 x 2 cm

Pathological Staging

pT 4 N0 M1 Stage: IV

Notes:

D1, D2, D3 (Stomach tumor)
D4 (Liver tumor)

[page 5 of 5]
1. **Histological pattern:**

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse			Streaming		
Mosaic			Storiform		
Necrosis			Fibrosis		
Lymphocytic Infiltration			Palisading		
Vascular Invasion			Cystic Degeneration		
Clusterized			Bleeding		
Alveolar Formation			Myxoid Change		
Indian File			Psammoma/Calcification		

2. **Cellular features:**

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: D ₁ 75%, D ₂ 70%, D ₃ 75%, D ₄ 90%											

2. **Cellular Differentiation:**

Well	Moderately	Poor

3. **Nuclear Atypia:**

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: Mucinous Adenocarcinoma, G-2

Comments: Dx : carcinoma invaded Liver

Source: NCI Genomic Data Commons file 6c78ac78-c288-48a5-8a88-efdf958f0ff0 (TCGA-CD-8529.D0B4CFF3-7C75-4D3C-93AE-7831CF4FEE61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).